Somatic mutation profile of tumor specimen TCGA-IB-7651-01A (aliquot TCGA-IB-7651-01A-11D-2154-08) from TCGA case TCGA-IB-7651, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.6 years (23,580 days).
Specimen TCGA-IB-7651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6a54a9c-b844-4a45-ae01-451a61bafc19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7651-10A (Blood Derived Normal), aliquot TCGA-IB-7651-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c2214bf-daa9-4ea5-bf48-8c0cb0eba599

The open-access MAF lists 17,551 somatic variants for this specimen: 12,874 protein-altering or splice-affecting, 4,290 silent, 387 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11,638, Silent 4,290, Nonsense Mutation 775, Splice Site 292, Intron 173, Splice Region 108, RNA 101, 3'UTR 47, Frame Shift Ins 38, 3'Flank 26, 5'Flank 23, 5'UTR 17.

Variants (750 of 17,551; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 95/476 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs1057520218; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGA | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 184/1168 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs386833423, CM1212279, COSV52805913; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH18A1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863225044, CM159181, COSV64662240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 52/196 reads (27%) | catalogued as rs886039558, CM920998, COSV65953893; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.2758C>T p.Q920* | Nonsense Mutation (SNP) | VAF 64/285 reads (22%) | catalogued as rs387906845, CM122484, COSV61371886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASNS | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 73/353 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1360484422, COSV51550189; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 46/236 reads (19%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- BRWD3 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 39/181 reads (22%) | catalogued as rs878853055, COSV64743451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C19orf12 | c.248C>T p.P83L (on ENST00000392278 / NM_001031726.3; = p.P72L on NM_031448.6) | Missense Mutation (SNP) | VAF 123/785 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201987973, CM132606, COSV100080683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1S | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | catalogued as rs550371466, COSV62939502; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CHAMP1 | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 79/376 reads (21%) | catalogued as rs879255261, CM162214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLEC14A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 128/623 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV60564301; called by muse, mutect2, varscan2
- CNTNAP2 | c.252G>A p.W84* | Nonsense Mutation (SNP) | VAF 54/303 reads (18%) | catalogued as rs267601384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.4438C>T p.R1480* | Nonsense Mutation (SNP) | VAF 43/263 reads (16%) | catalogued as rs72657321, CM1110333; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 129/702 reads (18%) | catalogued as rs1463828394, CM1514965, COSV57138314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 78/502 reads (16%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 53/277 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EXT1 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 54/303 reads (18%) | catalogued as rs1363815113, CM010236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FARSB | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 96/441 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753710639, COSV56050562; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs794728204, CM960637, CS098595, CS098596; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FBN1 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 124/670 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs768831064; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- GABRB3 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 85/475 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886037938, CM1314610, COSV54656624, COSV54667501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJB6 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 129/709 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs104894415, CM002605, CM131243, COSV53832458; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 88/266 reads (33%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- GNB1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 42/523 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs869312826; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GRIN2D | c.1999G>A p.V667I | Missense Mutation (SNP) | VAF 90/958 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886040861; ClinVar: pathogenic; called by muse, mutect2
- HBB | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 68/385 reads (18%) | catalogued as rs33991059, CM830030, CM950613; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXB | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 104/646 reads (16%) | catalogued as rs138914144; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IL10RA | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368287711, CM127465, COSV57139661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 54/306 reads (18%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ2 | c.927+1G>A p.X309_splice | Splice Site (SNP) | VAF 58/410 reads (14%) | catalogued as rs1555870346, CS154075; ClinVar: pathogenic; called by muse, varscan2
- KMT5B | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 38/305 reads (12%) | catalogued as rs1555028206, COSV58567208; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 93/662 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- MAPRE2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs864309720, CM1515097; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCCC2 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 124/705 reads (18%) | catalogued as rs763293192, COSV60157117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 54/263 reads (21%) | catalogued as rs770330684; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs121913644, CM011799; ClinVar: pathogenic / uncertain significance / likely benign; called by muse, mutect2, varscan2
- NARS2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 78/404 reads (19%) | catalogued as rs1057524183, COSV99807227; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NKX2-1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057524869, CM126957; ClinVar: likely pathogenic; called by muse, mutect2
- NOTCH3 | c.2411-1G>T p.X804_splice | Splice Site (SNP) | VAF 36/254 reads (14%) | catalogued as rs864621966, CS063353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OSMR | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 110/551 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs387906822, CM100173, COSV57087799; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- P3H2 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 56/324 reads (17%) | catalogued as rs377600857; ClinVar: pathogenic; called by muse, varscan2
- PGM1 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 68/291 reads (23%) | catalogued as rs397515423, CM128428, COSV100936558, COSV64300240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMM2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs200503569, CM971223, COSV51631655; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 40/260 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, varscan2
- RAD9B | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs747100389; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RNF168 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 98/517 reads (19%) | catalogued as rs201915239, CM112023; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 79/377 reads (21%) | catalogued as rs751477523, CM1212113, COSV50905127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPTOR | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 23/146 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs767783333, COSV60807635; called by muse, mutect2, varscan2
- SAMHD1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 79/373 reads (21%) | catalogued as rs121434517, CM093960, COSV53430327; ClinVar: pathogenic; called by muse, varscan2
- SCN4A | c.3938C>T p.T1313M | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121908547, CM941270, COSV71127251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4719C>T p.G1573= (on ENST00000333535 / NM_198056.3; = p.G1572= on NM_000335.5) | Silent (SNP) | VAF 81/420 reads (19%) | catalogued as rs754221948, CS099839, COSV61120528; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SERPINC1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 127/836 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs121909563, CM900039; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.982C>T p.R328W (on ENST00000263121; = p.R374W on NM_003073.5) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1568963596, COSV51954374, COSV51955307; ClinVar: pathogenic; called by muse, mutect2
- SNAP29 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 60/422 reads (14%) | catalogued as rs1315355162; ClinVar: pathogenic; called by muse, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 46/294 reads (16%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893815, CM050762, CM159806, COSV55442586, COSV55450248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNT2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397516466, CM107253; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 81/616 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- ZEB2 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 62/728 reads (9%) | catalogued as rs587784566, CM052018, COSV57966620; ClinVar: pathogenic; called by muse, mutect2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 131/740 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- A2M | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as rs1013277522; called by muse, mutect2
- A2ML1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 90/446 reads (20%) | catalogued as COSV55297981; called by muse, mutect2, varscan2
- A2ML1 | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs766181132; called by muse, mutect2, varscan2
- A3GALT2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57760659; called by muse, varscan2
- AADACL2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 72/441 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as rs764564206; called by muse, mutect2, varscan2
- AADACL3 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 90/507 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV60199410; called by muse, mutect2, varscan2
- AADACL4 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 66/628 reads (11%) | catalogued as rs1158072568; called by muse, varscan2
- AAGAB | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 160/884 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV56015883; called by muse, mutect2, varscan2
- AARS2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55116669; called by muse, mutect2, varscan2
- ABCA1 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as rs761275146; called by muse, mutect2, varscan2
- ABCA1 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759576379; called by muse, mutect2, varscan2
- ABCA10 | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 69/360 reads (19%) | catalogued as COSV99288766; called by muse, mutect2, varscan2
- ABCA12 | c.6739G>A p.G2247S (on ENST00000272895 / NM_173076.3; = p.G1929S on NM_015657.3) | Missense Mutation (SNP) | VAF 142/934 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55972901; called by muse, varscan2
- ABCA12 | c.5485G>T p.D1829Y (on ENST00000272895 / NM_173076.3; = p.D1511Y on NM_015657.3) | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV55967666; called by muse, mutect2, varscan2
- ABCA12 | c.4448T>C p.M1483T (on ENST00000272895 / NM_173076.3; = p.M1165T on NM_015657.3) | Missense Mutation (SNP) | VAF 95/578 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs763676072; called by muse, mutect2, varscan2
- ABCA12 | c.2141G>A p.R714Q (on ENST00000272895 / NM_173076.3; = p.R396Q on NM_015657.3) | Missense Mutation (SNP) | VAF 120/752 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs558822558, COSV55954651; called by muse, mutect2, varscan2
- ABCA12 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 93/608 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1384227542, COSV55954723; called by muse, varscan2
- ABCA13 | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as rs925443218; called by muse, mutect2, varscan2
- ABCA13 | c.7103C>T p.A2368V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.099); catalogued as rs1161053918, COSV101446894, COSV101447082; called by muse, mutect2, varscan2
- ABCA2 | c.7024C>T p.R2342W (on ENST00000614293; = p.R2312W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1173530564; called by muse, varscan2
- ABCA2 | c.2641G>A p.A881T (on ENST00000614293; = p.A851T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/471 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1396280548, COSV99687164; called by muse, mutect2, varscan2
- ABCA2 | c.1423C>T p.R475W (on ENST00000614293; = p.R445W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs773060335; called by muse, mutect2, varscan2
- ABCA3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs772668103, COSV57051667; called by muse, mutect2, varscan2
- ABCA4 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV64673762; called by muse, mutect2, varscan2
- ABCA4 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs774505934; called by muse, mutect2, varscan2
- ABCA7 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs866355955, COSV54035614; called by muse, mutect2
- ABCA7 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs541040666, COSV54029228; called by muse, mutect2, varscan2
- ABCA7 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 55/1302 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs1211691812; called by muse, mutect2
- ABCA7 | c.1620C>T p.D540= | Splice Region (SNP) | VAF 134/1697 reads (8%) | catalogued as rs1555683688; called by muse, mutect2
- ABCA8 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1037605600, COSV52213519; called by muse, mutect2
- ABCA9 | c.4698G>T p.Q1566H | Missense Mutation (SNP) | VAF 87/526 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV60630357; called by muse, mutect2, varscan2
- ABCA9 | c.3264G>A p.M1088I | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs967798034; called by muse, mutect2
- ABCA9 | c.2080C>A p.L694M | Missense Mutation (SNP) | VAF 252/1293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99046268; called by muse, mutect2, varscan2
- ABCB10 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 65/422 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV60619375; called by muse, mutect2, varscan2
- ABCB11 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 301/1251 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs781013887, CM097370; called by muse, mutect2, varscan2
- ABCB6 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs778457867; called by mutect2, varscan2
- ABCC11 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs983737712, COSV62324123; called by muse, mutect2, varscan2
- ABCC2 | c.3987G>T p.K1329N | Missense Mutation (SNP) | VAF 92/508 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64986972; called by muse, mutect2, varscan2
- ABCC4 | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs779403637, COSV65315057; called by muse, mutect2, varscan2
- ABCC5 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs937367157; called by muse, mutect2, varscan2
- ABCC6 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as rs771770753, COSV52742444; called by muse, mutect2, varscan2
- ABCC8 | c.4609-2A>C p.X1537_splice | Splice Site (SNP) | VAF 54/306 reads (18%) | catalogued as CS025926, CS061237; called by muse, mutect2, varscan2
- ABCG1 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 156/737 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV59205303; called by muse, mutect2, varscan2
- ABCG4 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 93/602 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201390504; called by muse, mutect2, varscan2
- ABHD13 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV101024215; called by muse, mutect2, varscan2
- ABHD15 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs899069152, COSV56196457; called by muse, mutect2, varscan2
- ABHD16A | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306314144; called by muse, mutect2, varscan2
- ABHD17A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs757885926; called by muse, varscan2
- ABHD17B | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 135/673 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV61007321; called by muse, mutect2, varscan2
- ABHD6 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 109/596 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs755459441, COSV55910608; called by muse, varscan2
- ABHD6 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 75/454 reads (17%) | catalogued as COSV55908395; called by muse, mutect2, varscan2
- ABI3BP | c.2680C>A p.L894M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400429816; called by muse, mutect2, varscan2
- ABI3BP | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1306785051; called by muse, mutect2, varscan2
- ABL1 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 84/472 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.352); catalogued as rs367600262; called by muse, varscan2
- ABLIM1 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 84/477 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs772414770, COSV53301185; called by muse, mutect2, varscan2
- ABO | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs782191109, COSV101505917; called by muse, mutect2, varscan2
- ABRAXAS1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 108/520 reads (21%) | catalogued as rs1046873224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABTB1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs147002334, COSV51740117; called by muse, mutect2
- AC004832.3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 88/866 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs144789689; called by muse, mutect2
- AC005833.1 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious, low confidence (0); catalogued as COSV52897505; called by muse, mutect2, varscan2
- AC008397.2 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV53207938; called by muse, mutect2, varscan2
- AC013489.1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs768762640; called by muse, mutect2, varscan2
- AC090517.4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 93/491 reads (19%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.998); catalogued as rs769699925; called by muse, mutect2, varscan2
- AC090517.4 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs756786580; called by muse, mutect2, varscan2
- AC097637.1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 104/747 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs937079388, COSV59727137; called by muse, mutect2, varscan2
- ACACB | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV58134677; called by muse, mutect2, varscan2
- ACACB | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs542111056; called by muse, mutect2, varscan2
- ACACB | c.2654C>T p.T885M | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs775472026; called by muse, varscan2
- ACACB | c.3016G>A p.V1006I | Missense Mutation (SNP) | VAF 130/675 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs768386735, COSV58140790; called by muse, varscan2
- ACACB | c.4469G>A p.R1490H | Missense Mutation (SNP) | VAF 140/697 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200016239; called by muse, mutect2, varscan2
- ACAD11 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs777865245; called by muse, varscan2
- ACADL | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 205/851 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749833302; called by muse, mutect2, varscan2
- ACADS | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 84/473 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99656624; called by muse, mutect2, varscan2
- ACAN | c.2917C>A p.L973I | Missense Mutation (SNP) | VAF 268/1351 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.279); catalogued as rs1277831540; called by muse, varscan2
- ACAN | c.5015C>A p.A1672D | Missense Mutation (SNP) | VAF 117/758 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.979); catalogued as COSV61362368; called by muse, mutect2, varscan2
- ACAP1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.572); catalogued as rs760010798; called by muse, mutect2, varscan2
- ACAT1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 69/437 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs749463321; called by muse, mutect2, varscan2
- ACBD3 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV64731081; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 40/404 reads (10%) | catalogued as COSV64729752; called by muse, mutect2
- ACCSL | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs751153787, COSV66583377; called by muse, mutect2, varscan2
- ACCSL | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 107/605 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as rs746976918, COSV66580653; called by muse, mutect2, varscan2
- ACKR4 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 186/1870 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs139794831; called by muse, mutect2
- ACLY | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1470344043; called by muse, mutect2, varscan2
- ACLY | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100709944; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 65/312 reads (21%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOT7 | c.1109C>T p.A370V (on ENST00000377855 / NM_181864.3; = p.A360V on NM_007274.4) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs578211150, COSV100830266; called by muse, mutect2, varscan2
- ACOX3 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs1056887479; called by muse, mutect2, varscan2
- ACSF3 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs746501634, COSV58080753; called by muse, varscan2
- ACSL3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 99/609 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as rs961458463; called by muse, mutect2, varscan2
- ACSL3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs376738660; called by muse, mutect2, varscan2
- ACSM2B | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.052); catalogued as COSV61660074; called by muse, mutect2, varscan2
- ACSM5 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100089725, COSV59372551; called by muse, mutect2, varscan2
- ACSM5 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 187/1170 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs113178652; called by muse, mutect2, varscan2
- ACSS2 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs934925605; called by muse, varscan2
- ACTA1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV64204077; called by muse, mutect2, varscan2
- ACTG2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61828609; called by muse, mutect2, varscan2
- ACTL9 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as rs372877504; called by muse, varscan2
- ACTL9 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs139329295, COSV61005953; called by muse, varscan2
- ACTN1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 83/496 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs747970717; called by muse, mutect2, varscan2
- ACTN2 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs794728968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN3 | c.2296C>T p.R766* | Nonsense Mutation (SNP) | VAF 59/298 reads (20%) | catalogued as rs751068262, COSV59748946; called by muse, mutect2, varscan2
- ACTR5 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 108/746 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); catalogued as rs761236439; called by muse, mutect2, varscan2
- ACVR1C | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 129/654 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54649489; called by muse, mutect2, varscan2
- ACVRL1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs1085307414, CM1513225, COSV101188116; called by muse, mutect2, varscan2
- ADAM18 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs372659771; called by muse, mutect2, varscan2
- ADAM19 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 216/1127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767863508; called by muse, mutect2, varscan2
- ADAM7 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV51536912; called by muse, mutect2, varscan2
- ADAMDEC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 156/818 reads (19%) | catalogued as rs376286647, COSV56474636; called by muse, mutect2, varscan2
- ADAMTS14 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750319577; called by muse, mutect2, varscan2
- ADAMTS16 | c.2258C>T p.T753I | Missense Mutation (SNP) | VAF 142/622 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as rs1304602687; called by muse, mutect2, varscan2
- ADAMTS17 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 133/718 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51474532; called by muse, mutect2, varscan2
- ADAMTS17 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 94/405 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.959); catalogued as rs545485140, COSV51492817; called by muse, mutect2, varscan2
- ADAMTS18 | c.3405C>T p.C1135= | Splice Region (SNP) | VAF 128/507 reads (25%) | catalogued as rs756700319; called by muse, mutect2, varscan2
- ADAMTS18 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 91/344 reads (26%) | catalogued as rs753594057, COSV51421755; called by muse, mutect2, varscan2
- ADAMTS18 | c.496T>G p.S166A | Missense Mutation (SNP) | VAF 102/431 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV51419811; called by muse, mutect2, varscan2
- ADAMTS2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 72/1276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52393165; called by muse, mutect2
- ADAMTS20 | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs375762593; called by muse, mutect2, varscan2
- ADAMTS3 | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV54403321; called by muse, mutect2, varscan2
- ADAMTS7 | c.2908A>G p.T970A | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV101183274; called by muse, varscan2
- ADAMTS7 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751121773, COSV101183094; called by muse, varscan2
- ADAMTS8 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs377662947; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1158664235; called by muse, mutect2
- ADAP2 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 172/883 reads (19%) | catalogued as rs772979991; called by muse, mutect2, varscan2
- ADAR | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333548641; called by muse, mutect2, varscan2
- ADARB2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV67214616; called by muse, mutect2, varscan2
- ADAT2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 74/453 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs532452116, COSV52793266; called by muse, mutect2, varscan2
- ADCK1 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 172/986 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765643989, COSV53086418; called by muse, mutect2, varscan2
- ADCK2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 106/594 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1247469314; called by muse, mutect2, varscan2
- ADCY1 | c.1541G>A p.C514Y | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99811660; called by muse, mutect2, varscan2
- ADCY10 | c.3845T>A p.I1282N | Missense Mutation (SNP) | VAF 169/984 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs1159689515; called by muse, varscan2
- ADCY10 | c.5A>C p.N2T | Missense Mutation (SNP) | VAF 125/561 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV63238327; called by muse, varscan2
- ADCY2 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs767145470, COSV57895322; called by muse, mutect2, varscan2
- ADCY3 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369803323; called by muse, mutect2, varscan2
- ADCY3 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV53165115, COSV99568914; called by muse, mutect2
- ADCY5 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1301023411; called by muse, mutect2, varscan2
- ADCY6 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764365272; called by muse, mutect2
- ADCY7 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs777973636; called by muse, mutect2, varscan2
- ADCY8 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53895566; called by muse, mutect2, varscan2
- ADCY8 | c.2413C>T p.L805= | Splice Region (SNP) | VAF 15/92 reads (16%) | catalogued as rs1203355929; called by muse, mutect2, varscan2
- ADCY9 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs142198070; called by muse, mutect2, varscan2
- ADD2 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV52456903; called by muse, mutect2
- ADD2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 148/509 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs782645890, COSV52464399; called by muse, mutect2, varscan2
- ADGRA1 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV66925390; called by muse, varscan2
- ADGRA3 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV51565480; called by muse, mutect2, varscan2
- ADGRA3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 91/564 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201944807; called by muse, mutect2, varscan2
- ADGRB1 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs771884806, COSV60101948; called by muse, mutect2, varscan2
- ADGRB2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.104); catalogued as rs1364413308, COSV99926007; called by muse, mutect2, varscan2
- ADGRD1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs755377639, COSV55439450, COSV55451837; called by muse, mutect2, varscan2
- ADGRD1 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs368828722, COSV55450685; called by muse, varscan2
- ADGRD1 | c.2529C>T p.L843= | Splice Region (SNP) | VAF 24/215 reads (11%) | catalogued as rs1186863596, COSV55451705; called by muse, varscan2
- ADGRG4 | c.3209C>T p.T1070I | Missense Mutation (SNP) | VAF 330/1486 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54957825; called by muse, varscan2
- ADGRG4 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 167/776 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV104381502; called by muse, varscan2
- ADGRL2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 105/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54662946, COSV54684897, COSV54688211; called by muse, mutect2, varscan2
- ADGRL2 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767811966, COSV54675510; called by muse, mutect2
- ADGRL2 | c.2693T>C p.L898P (on ENST00000370717 / NM_001366005.1; = p.L885P on NM_012302.4) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150031756; called by muse, mutect2, varscan2
- ADGRL2 | c.3520A>G p.T1174A | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV54673679; called by muse, mutect2
- ADGRL4 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100876627; called by muse, mutect2, varscan2
- ADH1B | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 111/560 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs147811380; called by muse, mutect2, varscan2
- ADH6 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 75/492 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367908790; called by muse, mutect2, varscan2
- ADHFE1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 139/788 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV99397880; called by muse, mutect2, varscan2
- ADHFE1 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768770100; called by muse, mutect2, varscan2
- ADIPOR1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 132/503 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781585434; called by muse, mutect2, varscan2
- ADM | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1415185208, COSV53403872; called by muse, mutect2, varscan2
- ADNP2 | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs373960178; called by muse, varscan2
- ADORA3 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53987022; called by muse, mutect2, varscan2
- ADRA2A | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 149/850 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54527129; called by muse, mutect2, varscan2
- ADRA2B | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1264061104; called by muse, mutect2, varscan2
- ADRA2C | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs769028798, COSV57466843; called by muse, varscan2
- AFDN | c.4900C>T p.R1634C (on ENST00000447894 / NM_001366320.1; = p.R1632C on NM_001040000.3) | Missense Mutation (SNP) | VAF 129/796 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as rs781720897, COSV60053577; called by muse, mutect2, varscan2
- AFF1 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 86/522 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as rs1434291124; called by muse, mutect2, varscan2
- AFF2 | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868933293; called by muse, mutect2, varscan2
- AFF3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 102/597 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs201587401, COSV100419579; called by muse, mutect2, varscan2
- AFF3 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 124/493 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs917787658; called by muse, mutect2, varscan2
- AFG1L | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 87/461 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs548447273; called by muse, mutect2, varscan2
- AGA | c.1007dup p.N336Kfs*5 | Frame Shift Ins (INS) | VAF 36/190 reads (19%) | catalogued as rs760478720; called by mutect2, varscan2
- AGA | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764539498, COSV52807062; called by muse, mutect2, varscan2
- AGAP3 | c.1855C>T p.R619* (on ENST00000622464; = p.R655* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 86/1784 reads (5%) | catalogued as rs1265218429; called by muse, mutect2
- AGAP4 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 120/1162 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782598354, COSV101432668; called by muse, varscan2
- AGAP4 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 90/730 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1301281010; called by muse, varscan2
- AGBL1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs376573682; called by muse, varscan2
- AGBL1 | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs369790993; called by muse, mutect2, varscan2
- AGBL5 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 174/961 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs775595367, COSV59935575; called by muse, mutect2, varscan2
- AGER | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs770047253, COSV100905016; called by muse, mutect2, varscan2
- AGFG1 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as rs746202265; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 114/1020 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGPAT4 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 84/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755678797, COSV57242883; called by muse, mutect2, varscan2
- AGPAT4 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs746506332, COSV57242484; called by muse, mutect2, varscan2
- AGRN | c.5747C>T p.A1916V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.657); catalogued as rs748726822; called by muse, varscan2
- AGTPBP1 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 26/382 reads (7%) | catalogued as COSV61268761; called by muse, mutect2
- AHCTF1 | c.5765T>G p.I1922S (on ENST00000366508; = p.I1896S on NM_015446.5) | Missense Mutation (SNP) | VAF 108/384 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1229023841; called by muse, mutect2, varscan2
- AHCY | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 89/543 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs750633041; called by muse, mutect2, varscan2
- AHI1 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662612; called by muse, mutect2, varscan2
- AHNAK | c.6083C>T p.P2028L | Missense Mutation (SNP) | VAF 404/2297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772630697; called by muse, mutect2, varscan2
- AHNAK | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 180/1024 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs1475704407; called by muse, mutect2, varscan2
- AHNAK2 | c.13469C>T p.A4490V | Missense Mutation (SNP) | VAF 199/1051 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.129); catalogued as rs745381931, COSV60932185; called by muse, mutect2, varscan2
- AHNAK2 | c.8872G>A p.A2958T | Missense Mutation (SNP) | VAF 378/1842 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs746292166; called by muse, mutect2, varscan2
- AHR | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as rs146411430; ClinVar: uncertain significance; called by muse, mutect2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AIFM1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 200/877 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV54854394; called by muse, mutect2, varscan2
- AIFM2 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57159218, COSV57159403; called by muse, mutect2, varscan2
- AIPL1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.583); catalogued as rs1329458187; called by muse, mutect2, varscan2
- AJM1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV56034715; called by muse, varscan2
- AK2 | c.182G>A p.R61Q (on ENST00000354858; = p.R103Q on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs762416285; called by muse, mutect2, varscan2
- AK7 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373883064, COSV50870925; called by muse, mutect2, varscan2
- AK8 | c.36dup p.E13Rfs*40 | Frame Shift Ins (INS) | VAF 26/217 reads (12%) | catalogued as rs757477831; called by mutect2, varscan2
- AK9 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372465779, COSV69850596; called by muse, mutect2, varscan2
- AKAP12 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 163/989 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1167352574, COSV53573402; called by muse, mutect2, varscan2
- AKAP17A | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 119/659 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368074392; called by muse, mutect2, varscan2
- AKAP7 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63505916; called by muse, mutect2, varscan2
- AKAP7 | c.862G>A p.G288R (on ENST00000431975 / NM_016377.4; = p.G21R on NM_004842.4) | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs1204957559, COSV53834836, COSV99541860; called by muse, varscan2
- AKAP8L | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 304/1450 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs903544730, COSV68474542; called by muse, mutect2, varscan2
- AKR1B15 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs766363195, COSV101423350, COSV101423381; called by muse, mutect2, varscan2
- AKR1C1 | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 104/601 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.056); catalogued as COSV66499169; called by muse, varscan2
- AKTIP | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 94/555 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs776539900; called by muse, mutect2, varscan2
- AL117348.2 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 35/186 reads (19%) | catalogued as rs1384587977; called by muse, mutect2, varscan2
- AL136295.1 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1225394984, COSV99938365; called by muse, mutect2, varscan2
- AL162417.1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.018); catalogued as rs1479545060; called by muse, mutect2, varscan2
- AL358113.1 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 95/430 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs764463413, COSV61958730; called by muse, mutect2, varscan2
- AL592490.1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 91/515 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs751419926; called by muse, mutect2, varscan2
- AL592490.1 | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs757592226; called by muse, mutect2, varscan2
- AL645922.1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 94/637 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs904279699; called by muse, mutect2, varscan2
- ALDH16A1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 98/453 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs377255662; called by muse, mutect2, varscan2
- ALDH1L2 | c.2125C>T p.L709F | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs749793908; called by muse, mutect2, varscan2
- ALDH3A1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771640925; called by muse, mutect2, varscan2
- ALDH3B1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 93/612 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs200028780; called by muse, mutect2, varscan2
- ALDH6A1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339163343, COSV63247235; called by muse, mutect2, varscan2
- ALG12 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 39/326 reads (12%) | PolyPhen possibly damaging (0.899); catalogued as rs200241636; called by muse, mutect2, varscan2
- ALG5 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.991); catalogued as rs772872038; called by muse, mutect2, varscan2
- ALG9 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782123768, COSV67644339; called by muse, mutect2, varscan2
- ALK | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs978946990, COSV66558734; called by muse, mutect2, varscan2
- ALKBH1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs1170281730, COSV99380485; called by muse, mutect2, varscan2
- ALKBH2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 166/902 reads (18%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs573894170; called by muse, mutect2, varscan2
- ALKBH6 | c.220C>T p.R74W (on ENST00000252984 / NM_001297701.2; = p.R102W on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs149341422; called by muse, mutect2, varscan2
- ALLC | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 146/636 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs760484262, COSV99378398; called by muse, mutect2, varscan2
- ALMS1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 193/896 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV52502437; called by muse, mutect2, varscan2
- ALPI | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 101/622 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761639198; called by muse, mutect2, varscan2
- ALPK1 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV51593441; called by muse, mutect2, varscan2
- ALPK2 | c.5804G>A p.R1935H | Missense Mutation (SNP) | VAF 53/553 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753524863, COSV100864513; called by muse, mutect2
- ALPK3 | c.3194G>A p.G1065D | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs770821477; called by muse, varscan2
- ALPK3 | c.4600G>A p.E1534K | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs765401924; called by muse, mutect2, varscan2
- ALPL | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757771793, CM068249; called by muse, mutect2, varscan2
- ALPP | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 93/1039 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67397722; called by muse, mutect2
- ALS2 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 194/807 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs759250548; called by muse, mutect2, varscan2
- ALX4 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 163/874 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750798110, COSV100241111; called by muse, mutect2
- AMBN | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1402964777; called by muse, mutect2, varscan2
- AMBP | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 92/585 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768762324; called by muse, mutect2, varscan2
- AMBRA1 | c.3670C>T p.R1224* (on ENST00000458649 / NM_001367468.1; = p.R1134* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 56/319 reads (18%) | catalogued as rs1023861260, COSV54053486; called by muse, mutect2, varscan2
- AMER1 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV100365600; called by muse, mutect2, varscan2
- AMHR2 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 142/702 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs1565839762; called by muse, mutect2, varscan2
- AMHR2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 298/1381 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM151253, COSV57687076; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 59/365 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMOT | c.1708C>T p.R570* (on ENST00000371959 / NM_001113490.1; = p.R161* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 272/1320 reads (21%) | catalogued as COSV59063802, COSV59066847; called by muse, mutect2, varscan2
- AMOTL2 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 88/548 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.622); catalogued as rs183770550; called by muse, varscan2
- AMPD3 | c.655G>A p.D219N (on ENST00000396553 / NM_001025389.2; = p.D228N on NM_000480.3) | Missense Mutation (SNP) | VAF 86/563 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1205243330; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 106/596 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, varscan2
- AMTN | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 91/584 reads (16%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs374431307; called by muse, mutect2, varscan2
- ANAPC1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1340627447; called by muse, mutect2, varscan2
- ANAPC2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 111/666 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1225949647, COSV58808335; called by muse, mutect2, varscan2
- ANAPC5 | c.554G>T p.R185I | Missense Mutation (SNP) | VAF 212/1199 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV55843321; called by muse, mutect2, varscan2
- ANGPTL3 | c.1135T>G p.L379V | Missense Mutation (SNP) | VAF 117/551 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.644); catalogued as rs1355948879; called by muse, mutect2, varscan2
- ANGPTL6 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs993005769; called by muse, mutect2, varscan2
- ANK1 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs146518198, COSV99224772; called by muse, mutect2, varscan2
- ANK3 | c.7672C>T p.R2558C | Missense Mutation (SNP) | VAF 129/746 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs375600068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKIB1 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as rs760743621, COSV56061265; called by muse, mutect2, varscan2
- ANKIB1 | c.2957C>A p.A986D | Missense Mutation (SNP) | VAF 103/508 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV99729215; called by muse, mutect2, varscan2
- ANKK1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 71/559 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs760834011; called by muse, mutect2, varscan2
- ANKK1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV58274022; called by muse, mutect2, varscan2
- ANKK1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1441991387; called by muse, mutect2
- ANKLE2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1346187941, COSV100514380; called by muse, mutect2, varscan2
- ANKLE2 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61709642; called by muse, mutect2, varscan2
- ANKRD1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65467117, COSV65468105; called by muse, mutect2, varscan2
- ANKRD11 | c.5756C>T p.A1919V | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs773848887, COSV56370607; called by muse, mutect2, varscan2
- ANKRD11 | c.5284G>A p.D1762N | Missense Mutation (SNP) | VAF 129/499 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs1567564467; called by muse, mutect2, varscan2
- ANKRD11 | c.4426C>T p.H1476Y | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs1224940452; called by muse, mutect2, varscan2
- ANKRD13C | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as rs899146901; called by muse, varscan2
- ANKRD17 | c.7270C>A p.P2424T | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV100429605; called by muse, mutect2
- ANKRD17 | c.4654G>A p.A1552T | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV58227528; called by muse, mutect2, varscan2
- ANKRD49 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.76); catalogued as COSV100119433; called by muse, mutect2, varscan2
- ANKRD50 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 236/1268 reads (19%) | catalogued as rs759095901, COSV72385021; called by muse, mutect2, varscan2
- ANKRD50 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 88/485 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs774438602; called by muse, mutect2, varscan2
- ANKRD50 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 165/831 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101539018; called by muse, mutect2, varscan2
- ANKRD52 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759480642; called by muse, varscan2
- ANKRD52 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs779734308; called by muse, mutect2, varscan2
- ANKS1B | c.2420-1G>T p.X807_splice (on ENST00000547776 / NM_152788.4; = p.G33* on NM_020140.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 58/265 reads (22%) | catalogued as COSV100228820; called by muse, mutect2, varscan2
- ANKS3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 70/964 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs373599022; called by muse, mutect2
- ANKS3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs372034547; called by muse, mutect2, varscan2
- ANKS6 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs746172737, COSV100782401; called by muse, varscan2
- ANKS6 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 31/218 reads (14%) | catalogued as rs1306952839, COSV62049044; called by muse, varscan2
- ANLN | c.2611G>A p.V871I | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.705); catalogued as rs1178556709; called by muse, mutect2, varscan2
- ANO2 | c.1529C>T p.T510M (on ENST00000356134 / NM_001278597.3; = p.T514M on NM_001278596.3) | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1400108513; called by muse, mutect2, varscan2
- ANO3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 156/913 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); catalogued as rs758733002, COSV56785193; called by muse, mutect2, varscan2
- ANO3 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1195721937; called by muse, mutect2, varscan2
- ANO3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 253/1394 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.403); catalogued as rs1169500577; called by muse, mutect2, varscan2
- ANO3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 90/505 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV104375648; called by muse, varscan2
- ANO4 | c.44T>G p.V15G | Missense Mutation (SNP) | VAF 104/586 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV54593246; called by muse, varscan2
- ANO7 | c.2024G>A p.R675H (on ENST00000274979; = p.R621H on NM_001370694.2) | Missense Mutation (SNP) | VAF 94/507 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs545708893, COSV51471794, COSV51475315; called by muse, mutect2, varscan2
- ANO8 | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 184/1159 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs945267118; called by muse, mutect2, varscan2
- ANXA6 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1273547419; called by muse, mutect2, varscan2
- ANXA6 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 82/398 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905412; called by muse, mutect2, varscan2
- AOC1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760642299; called by muse, varscan2
- AOC1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 70/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62871369; called by muse, mutect2, varscan2
- AOC2 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs775599309; called by muse, mutect2, varscan2
- AP1B1 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as rs750580486; called by muse, varscan2
- AP1G2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 49/377 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757969661; called by muse, mutect2, varscan2
- AP3D1 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs765841034; ClinVar: uncertain significance; called by muse, varscan2
- AP3D1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs778701220; called by muse, mutect2, varscan2
- AP3M1 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs768675374; called by muse, mutect2, varscan2
- AP3M2 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 182/997 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1425052771, COSV99441377; called by muse, mutect2, varscan2
- AP4B1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454940627; called by muse, mutect2, varscan2
- APAF1 | c.683G>A p.R228H (on ENST00000551964 / NM_181861.2; = p.R217H on NM_001160.3) | Missense Mutation (SNP) | VAF 80/442 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1452948462, COSV59665440; called by muse, mutect2, varscan2
- APAF1 | c.970G>A p.V324I (on ENST00000551964 / NM_181861.2; = p.V313I on NM_001160.3) | Missense Mutation (SNP) | VAF 144/786 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs778546488; called by muse, varscan2
- APAF1 | c.2032G>A p.D678N (on ENST00000551964 / NM_181861.2; = p.D667N on NM_001160.3) | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100452226; called by muse, mutect2, varscan2
- APBA2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs773916156, COSV67105402; called by muse, mutect2
- APBA2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1304600903; called by muse, mutect2, varscan2
- APBB1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1190353452, COSV54973465; called by muse, mutect2, varscan2
- APBB2 | c.1585C>T p.R529* (on ENST00000295974 / NM_001166050.2; = p.R530* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 60/418 reads (14%) | catalogued as rs757146916, COSV55946364; called by muse, varscan2
- APBB3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 206/1262 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs774287378; called by muse, mutect2, varscan2
- APC | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs587779805, COSV57325373, COSV57365922, COSV99965333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs779107230, COSV52020590; called by muse, mutect2
- APCDD1L | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776892324, COSV64486065; called by muse, mutect2
- APEH | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs975607104; called by muse, mutect2, varscan2
- API5 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66634815; called by muse, mutect2, varscan2
- APLF | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs542229761; called by muse, mutect2, varscan2
- APLP2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs776057355, COSV53843055; called by muse, mutect2, varscan2
- APOA5 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV57063859; called by muse, mutect2, varscan2
- APOA5 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV57063080; called by muse, mutect2, varscan2
- APOB | c.10673G>A p.R3558H | Missense Mutation (SNP) | VAF 135/462 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs762035088, COSV51930542; called by muse, varscan2
- APOB | c.2738C>A p.A913D | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51934544; called by muse, mutect2
- APOB | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 134/808 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs548108916, CD096704, COSV51939155; called by muse, mutect2, varscan2
- APOBEC3G | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 157/938 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs542681958; called by muse, mutect2, varscan2
- APOL3 | c.1012C>T p.R338W (on ENST00000349314 / NM_145640.2; = p.R267W on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs765336780, COSV62579174; called by muse, mutect2, varscan2
- APP | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100696342; called by muse, mutect2, varscan2
- APPL1 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 174/1060 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs576774339, COSV55700427; called by muse, mutect2, varscan2
- AQR | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV50033454; called by muse, mutect2, varscan2
- ARAP2 | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs139889832; called by muse, mutect2, varscan2
- ARAP3 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 145/699 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53350884; called by muse, mutect2, varscan2
- ARF1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 56/587 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV55256221; called by muse, mutect2
- ARFGAP1 | c.684C>T p.G228= | Splice Region (SNP) | VAF 10/59 reads (17%) | catalogued as rs6122111, COSV100796635; called by mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 82/753 reads (11%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF1 | c.4847C>T p.A1616V | Missense Mutation (SNP) | VAF 118/536 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs774229384; called by muse, mutect2, varscan2
- ARFGEF1 | c.4781C>A p.A1594D | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV51610473; called by muse, mutect2
- ARFGEF1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 73/507 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764719716, COSV51607682; called by muse, mutect2, varscan2
- ARFGEF3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 67/396 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs778211953, COSV99294016; called by muse, mutect2, varscan2
- ARG2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 60/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746928269, COSV53619040; called by muse, mutect2, varscan2
- ARGLU1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 42/876 reads (5%) | catalogued as COSV62271739; called by muse, mutect2
- ARHGAP11B | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776419726; called by muse, mutect2, varscan2
- ARHGAP12 | c.1989G>T p.Q663H | Missense Mutation (SNP) | VAF 54/391 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV60961289; called by muse, mutect2, varscan2
- ARHGAP19 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 85/489 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs368334954; called by muse, mutect2, varscan2
- ARHGAP20 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs1199974988, COSV52813813; called by muse, mutect2, varscan2
- ARHGAP21 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 101/620 reads (16%) | catalogued as COSV57604563; called by muse, mutect2, varscan2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 95/480 reads (20%) | catalogued as COSV51987040; called by muse, mutect2, varscan2
- ARHGAP27 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV51818143; called by muse, mutect2, varscan2
- ARHGAP28 | c.776C>T p.P259L (on ENST00000383472 / NM_001366230.1; = p.P100L on NM_001010000.3) | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1223142867, COSV51645969; called by muse, varscan2
- ARHGAP30 | c.2948G>A p.R983Q (on ENST00000368013 / NM_001025598.2; = p.R772Q on NM_181720.3) | Missense Mutation (SNP) | VAF 145/771 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs376108588; called by muse, mutect2, varscan2
- ARHGAP32 | c.5848C>T p.R1950* (on ENST00000310343 / NM_001378025.1; = p.R1601* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 120/547 reads (22%) | catalogued as rs543689971; called by muse, mutect2, varscan2
- ARHGAP32 | c.5543C>T p.T1848M (on ENST00000310343 / NM_001378025.1; = p.T1499M on NM_014715.4) | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs577826686; called by muse, mutect2, varscan2
- ARHGAP33 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50152830; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 85/460 reads (18%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP39 | c.2815G>A p.E939K (on ENST00000276826 / NM_001308208.2; = p.E970K on NM_025251.2) | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1277135072, COSV52769573; called by muse, mutect2, varscan2
- ARHGAP39 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs777473259; called by muse, mutect2, varscan2
- ARHGDIA | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs1357682654, COSV53906549; called by muse, mutect2, varscan2
- ARHGEF1 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as COSV61528473; called by muse, mutect2, varscan2
- ARHGEF11 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747105074; called by muse, mutect2, varscan2
- ARHGEF12 | c.3017A>C p.N1006T | Missense Mutation (SNP) | VAF 77/925 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV100754695; called by muse, mutect2
- ARHGEF12 | c.3324G>T p.Q1108H | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100755117; called by muse, mutect2, varscan2
- ARHGEF12 | c.3538G>A p.D1180N | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV100754977; called by muse, mutect2
- ARHGEF16 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 44/551 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV65682816; called by muse, mutect2
- ARHGEF18 | c.743G>A p.R248H (on ENST00000359920 / NM_001130955.2; = p.R144H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs960519789, COSV60469637; called by muse, mutect2, varscan2
- ARHGEF18 | c.2278C>A p.L760I (on ENST00000359920 / NM_001130955.2; = p.L656I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/548 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as rs772213575; called by muse, mutect2, varscan2
- ARHGEF19 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 94/433 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs777439419, COSV54617537; called by muse, mutect2, varscan2
- ARHGEF26 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as rs762062887; called by muse, mutect2, varscan2
- ARHGEF37 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 103/624 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs745325357; called by muse, mutect2, varscan2
- ARHGEF5 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 116/1724 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs781161445; called by muse, mutect2
- ARHGEF6 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 233/1021 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.711); catalogued as rs890270237; called by muse, mutect2, varscan2
- ARHGEF7 | c.889T>C p.Y297H (on ENST00000375741 / NM_001113511.2; = p.Y119H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762742190; called by muse, mutect2, varscan2
- ARID1A | c.1833G>T p.Q611H | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV61370662; called by muse, mutect2, varscan2
- ARID1A | c.5398A>T p.N1800Y | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs551963483; called by muse, mutect2, varscan2
- ARID2 | c.4777A>G p.T1593A | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs771509959; called by muse, mutect2, varscan2
- ARID4B | c.1926+2T>C p.X642_splice | Splice Site (SNP) | VAF 32/213 reads (15%) | catalogued as rs1356246985; called by muse, varscan2
- ARL10 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 176/648 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs148633924; called by muse, varscan2
- ARL4A | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as COSV100775945; called by muse, mutect2, varscan2
- ARL4D | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV60721725; called by muse, mutect2, varscan2
- ARMC1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 106/572 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs927221782; called by muse, mutect2, varscan2
- ARMC2 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777531717; called by muse, mutect2, varscan2
- ARMC3 | c.1256C>G p.A419G | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs935988752; called by muse, varscan2
- ARMC3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 78/437 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023972, COSV53059669; called by muse, mutect2, varscan2
- ARMC6 | c.1137G>T p.Q379H (on ENST00000392336; = p.Q354H on NM_033415.4) | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1345124255; called by muse, mutect2, varscan2
- ARMC6 | c.1216C>T p.R406C (on ENST00000392336; = p.R381C on NM_033415.4) | Missense Mutation (SNP) | VAF 148/757 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs200832309; called by muse, mutect2, varscan2
- ARMCX6 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62680759; called by muse, mutect2, varscan2
- ARMH3 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs769392626, COSV100899005, COSV64234815; called by muse, mutect2, varscan2
- ARPC5L | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414526; called by muse, mutect2, varscan2
- ARRB2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs776875048, COSV99347043; called by muse, mutect2, varscan2
- ARRDC1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 161/811 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765783709, COSV58378389; called by muse, mutect2, varscan2
- ARRDC2 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 82/554 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99716741; called by muse, varscan2
- ARRDC4 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 81/440 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1298402050; called by muse, mutect2, varscan2
- ARSB | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs767794291, COSV99364454; called by muse, mutect2, varscan2
- ARSG | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748352893; called by muse, varscan2
- ARSI | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100156134; called by muse, mutect2, varscan2
- ARSL | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101140388; called by muse, mutect2, varscan2
- ARVCF | c.1927C>A p.L643I | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as COSV54264781; called by muse, mutect2, varscan2
- ARVCF | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs758305327; called by muse, mutect2, varscan2
- AS3MT | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1329107684; called by muse, mutect2, varscan2
- ASAH1 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 104/660 reads (16%) | catalogued as rs771847002, CM1513461; called by muse, varscan2
- ASAP1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as rs753264322; called by muse, mutect2, varscan2
- ASAP2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 76/813 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs757499704, COSV55635586; called by muse, mutect2
- ASAP3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 79/437 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as rs113419927; called by muse, mutect2, varscan2
- ASB10 | c.1393G>A p.V465M (on ENST00000420175 / NM_001142459.2; = p.V450M on NM_080871.4) | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs777761428, COSV51996767, COSV51996981; called by muse, mutect2, varscan2
- ASB10 | c.629G>A p.R210Q (on ENST00000420175 / NM_001142459.2; = p.R195Q on NM_080871.4) | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.974); catalogued as rs748235039; called by muse, mutect2, varscan2
- ASB11 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 214/943 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs201426380; called by muse, mutect2, varscan2
- ASB2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778570607, COSV60110654; called by muse, varscan2
- ASB3 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs371519069; called by muse, varscan2
- ASB5 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 161/873 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs371144681; called by muse, mutect2, varscan2
- ASB9 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV66851348; called by muse, mutect2, varscan2
- ASCC3 | c.4855C>T p.H1619Y | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64977668; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 92/752 reads (12%) | catalogued as rs761154268; called by mutect2, varscan2
- ASIC1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs750013341, COSV57317871; called by muse, mutect2, varscan2
- ASIC3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140048490, COSV52507533; called by muse, varscan2
- ASIC4 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs758893039, COSV61733521; called by muse, varscan2
- ASIC4 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs967035531; called by muse, varscan2
- ASIC4 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 68/356 reads (19%) | catalogued as COSV61731497; called by muse, varscan2
- ASNS | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs769236847, COSV99446150; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, varscan2
- ASPH | c.1737A>C p.K579N | Missense Mutation (SNP) | VAF 163/809 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV65245061; called by muse, mutect2, varscan2
- ASPH | c.1605G>A p.M535I | Missense Mutation (SNP) | VAF 272/1514 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs754531033; called by muse, mutect2, varscan2
- ASPHD2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 128/668 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1192540003, COSV53219670; called by muse, mutect2, varscan2
- ASPM | c.8752G>T p.A2918S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1022531032; called by muse, mutect2, varscan2
- ASPM | c.2891C>T p.A964V | Missense Mutation (SNP) | VAF 107/670 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54126822; called by muse, mutect2, varscan2
- ASPM | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 174/1090 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1382867738, COSV54129445; called by muse, mutect2, varscan2
- ASTN1 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV56067489, COSV99923073; called by muse, varscan2
- ASXL1 | c.3896G>A p.G1299D | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as rs1416591993, COSV60115642; called by muse, mutect2, varscan2
- ASXL2 | c.3973C>T p.P1325S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs757158204; called by muse, mutect2, varscan2
- ASXL3 | c.5215C>T p.R1739C | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs376309030; called by muse, mutect2, varscan2
- ATAD3A | c.825G>A p.R275= | Splice Region (SNP) | VAF 110/470 reads (23%) | catalogued as rs1193029381; called by muse, mutect2, varscan2
- ATAD3A | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs779111850, COSV59234862; called by muse, mutect2, varscan2
- ATF3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 40/506 reads (8%) | catalogued as rs756952643, COSV58378340; called by muse, mutect2
- ATF7IP | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 71/467 reads (15%) | catalogued as COSV53773884, COSV99661515; called by muse, mutect2, varscan2
- ATF7IP2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 99/509 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs763026987, COSV100202586; called by muse, mutect2, varscan2
- ATG14 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1309857294; called by muse, mutect2, varscan2
- ATG2A | c.5621C>T p.S1874L | Missense Mutation (SNP) | VAF 66/407 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs369775317; called by muse, mutect2, varscan2
- ATG2B | c.5441C>T p.T1814M | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs953224520; called by muse, mutect2, varscan2
- ATG2B | c.4064C>T p.A1355V | Missense Mutation (SNP) | VAF 123/688 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs757709459; called by muse, mutect2, varscan2
- ATM | c.7058C>A p.P2353H | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53750148, COSV53762435; called by muse, mutect2, varscan2
- ATM | c.7375C>T p.R2459C | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs730881383, CM142728, COSV53769970, COSV99069701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8339T>G p.L2780R | Missense Mutation (SNP) | VAF 142/787 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53726070, COSV53744128; called by muse, mutect2, varscan2
- ATM | c.8801C>T p.T2934I | Missense Mutation (SNP) | VAF 101/672 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53748307; called by muse, mutect2, varscan2
- ATMIN | c.1923C>A p.F641L | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55146535; called by muse, mutect2, varscan2
- ATN1 | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 112/568 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV63110180; called by muse, varscan2
- ATP10A | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as rs1288765192, COSV100791095; called by muse, mutect2, varscan2
- ATP11A | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV99370525; called by muse, mutect2, varscan2
- ATP11B | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 196/1131 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as rs766793854; called by muse, mutect2, varscan2
- ATP13A4 | c.2025G>A p.T675= | Splice Region (SNP) | VAF 67/300 reads (22%) | catalogued as rs200015919; called by muse, mutect2, varscan2
- ATP13A5 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 134/709 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100665589; called by muse, varscan2
- ATP13A5 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 150/721 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as rs928557187, COSV100665011; called by muse, varscan2
- ATP1A1 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV55194776, COSV99814638; called by muse, mutect2
- ATP1A2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV63406099; called by muse, mutect2, varscan2
- ATP1A3 | c.1804G>A p.V602I (on ENST00000545399 / NM_001256214.2; = p.V589I on NM_152296.5) | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57487073; called by muse, mutect2, varscan2
- ATP1A4 | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 171/704 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1403402363; called by muse, mutect2, varscan2
- ATP2A1 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 158/812 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99061647; called by muse, mutect2, varscan2
- ATP2A1 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 46/588 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754020765, COSV62869676; called by muse, mutect2
- ATP2A2 | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs151157805; called by muse, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53804028; called by muse, varscan2
- ATP2B2 | c.1673C>T p.T558M (on ENST00000352432; = p.T524M on NM_001683.5) | Missense Mutation (SNP) | VAF 91/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314290874, COSV59495490; called by muse, mutect2, varscan2
- ATP2C1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 94/600 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358466833, COSV60756111; called by muse, mutect2, varscan2
- ATP2C2 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 260/1198 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.564); catalogued as rs748758130; called by muse, varscan2
- ATP2C2 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 81/1024 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV52292727; called by muse, mutect2
- ATP4A | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99383290; called by muse, mutect2, varscan2
- ATP4A | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 194/1836 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as rs868366556; called by muse, varscan2
- ATP5F1A | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 71/403 reads (18%) | catalogued as COSV56360571; called by muse, mutect2, varscan2
- ATP5F1C | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as rs146307767, COSV59620924; called by muse, mutect2, varscan2
- ATP5MD | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs773059267, COSV100428351; called by muse, mutect2, varscan2
- ATP6V0A1 | c.236T>G p.I79S | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV52875810; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2258-1G>T p.X753_splice | Splice Site (SNP) | VAF 57/533 reads (11%) | catalogued as CS148446, COSV100022692; called by muse, mutect2, varscan2
- ATP6V1B2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV52355184; called by muse, varscan2
- ATP6V1F | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs572332618; called by muse, mutect2, varscan2
- ATP8A1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 94/490 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV52541405; called by muse, varscan2
- ATP8A1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 56/274 reads (20%) | catalogued as rs769033596; called by muse, varscan2
- ATP8B1 | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1287415755; called by muse, mutect2
- ATP8B1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766847937, CM166686, COSV99377255; called by muse, mutect2, varscan2
- ATP8B3 | c.753C>T p.A251= | Splice Region (SNP) | VAF 31/233 reads (13%) | catalogued as rs747132737; called by muse, mutect2, varscan2
- ATP8B4 | c.2141+1G>T p.X714_splice | Splice Site (SNP) | VAF 64/317 reads (20%) | catalogued as rs1167059107; called by muse, mutect2, varscan2
- ATP8B4 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs762612545, COSV52714016; called by muse, mutect2, varscan2
- ATP9A | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1328628299, COSV58766179; called by muse, mutect2, varscan2
- ATP9A | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 102/1346 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs751286712, COSV58762861; called by muse, mutect2
- ATP9B | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56950876; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 65/305 reads (21%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- ATXN7 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 135/689 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753027029; called by muse, mutect2, varscan2
- AUH | c.897C>T p.V299= | Splice Region (SNP) | VAF 52/302 reads (17%) | catalogued as COSV57863139; called by muse, varscan2
- AUH | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342948; called by muse, mutect2
- AUNIP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as rs200152788; called by muse, mutect2, varscan2
- AUTS2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61388180; called by muse, mutect2, varscan2
- AUTS2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs756334229; called by muse, mutect2, varscan2
- AUTS2 | c.3776G>A p.R1259Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148604002; called by mutect2, varscan2
- AXIN1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs369325988, COSV51986557; called by muse, mutect2, varscan2
- AZGP1 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV52798890; called by muse, mutect2, varscan2
- AZU1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 166/693 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as rs921017716; called by muse, mutect2, varscan2
- B3GALNT2 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 280/1107 reads (25%) | catalogued as rs762259872; called by muse, mutect2, varscan2
- B3GALT4 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs761062678; called by muse, mutect2, varscan2
- B3GAT1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs144109297; called by muse, mutect2, varscan2
- B3GNT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 659/2441 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs766045424, COSV57345249; called by muse, mutect2, varscan2
- B3GNT4 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778158051; called by muse, mutect2, varscan2
- B3GNT6 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1346393960; called by muse, mutect2
- B3GNT7 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 193/677 reads (29%) | catalogued as rs1479181667; called by muse, mutect2, varscan2
- B4GALNT3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 48/308 reads (16%) | catalogued as rs780455486, COSV56752734; called by muse, mutect2, varscan2
- B4GALNT4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1318493043; called by muse, mutect2, varscan2
- B4GALNT4 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1488170429, COSV100327951; called by muse, mutect2
- BABAM1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs766735279, COSV53105514; called by muse, mutect2, varscan2
- BAG5 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 141/648 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1277150705; called by muse, mutect2, varscan2
- BAG6 | c.2479C>T p.R827* (on ENST00000676571; = p.R780* on NM_080702.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 126/727 reads (17%) | catalogued as COSV52994248; called by muse, mutect2, varscan2
- BAHCC1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs544465445, COSV57029799; called by muse, mutect2
- BAHD1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as rs373140549; called by muse, mutect2
- BAHD1 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 196/1080 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as rs752866319; called by muse, mutect2, varscan2
- BAIAP2L2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs780130920; called by muse, mutect2, varscan2
- BAIAP3 | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 138/788 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs148005520; called by muse, varscan2
- BAMBI | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 70/486 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65003376; called by muse, mutect2, varscan2
- BARD1 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 152/906 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53610594, COSV53614010; called by muse, mutect2, varscan2
- BARD1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs751357679; called by muse, mutect2, varscan2
- BASP1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758132970, COSV59469386; called by muse, mutect2, varscan2
- BAZ2A | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs775297286, COSV51632740; called by muse, mutect2, varscan2
- BAZ2B | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 122/741 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100600909; called by muse, mutect2, varscan2
- BBS4 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV51437174; called by muse, mutect2, varscan2
- BBS5 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1418558050; called by muse, mutect2, varscan2
- BBS7 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 21/311 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV52657699; called by muse, mutect2
- BCAN | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs780148527, COSV61255913; called by muse, mutect2, varscan2
- BCAN | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 241/910 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245040424, COSV61258287; called by muse, mutect2, varscan2
- BCAR1 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs142603608; called by muse, mutect2, varscan2
- BCAS3 | c.1721C>T p.S574L (on ENST00000390652 / NM_001353144.2; = p.S559L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs959545152, COSV66783081; called by muse, mutect2, varscan2
- BCAT2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV60273709; called by muse, mutect2, varscan2
- BCHE | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100012166, COSV52261350; called by muse, mutect2, varscan2
- BCL11B | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV61733894; called by muse, varscan2
- BCL9L | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs566574462, COSV52688055; called by muse, mutect2, varscan2
- BCL9L | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.388); catalogued as rs1316558261, COSV52684424; called by muse, mutect2, varscan2
- BDNF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 144/847 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779034534, COSV59233109; called by muse, mutect2, varscan2
- BDP1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs759542204; called by muse, mutect2, varscan2
- BDP1 | c.3085A>G p.I1029V | Missense Mutation (SNP) | VAF 98/531 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs749812637, COSV62428829; called by muse, mutect2, varscan2
- BEND6 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 138/804 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs371013253; called by muse, mutect2, varscan2
- BEST1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs148326372; called by mutect2, varscan2
- BEST4 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 48/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs16832247; called by muse, mutect2
- BFAR | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 163/780 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761912529, COSV55492914; called by muse, mutect2, varscan2
- BHLHE22 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV58862122; called by muse, mutect2
- BHMT2 | c.297G>T p.R99S | Missense Mutation (SNP) | VAF 128/682 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV54871855; called by muse, mutect2, varscan2
- BICD1 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 125/639 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1009886917, COSV55681459; called by muse, mutect2, varscan2
- BICDL1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 123/671 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs750229943; called by muse, mutect2, varscan2
- BICDL2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs376295108; called by muse, varscan2
- BICRAL | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.381); catalogued as rs764629909; called by muse, mutect2, varscan2
- BIN3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs765112578; called by muse, mutect2, varscan2
- BIRC2 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 80/473 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as rs375296936; called by muse, mutect2, varscan2
- BIRC6 | c.6872G>A p.R2291H | Missense Mutation (SNP) | VAF 125/497 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs551174027, COSV70200188; called by muse, mutect2, varscan2
- BIRC6 | c.11212G>A p.A3738T | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs1390075882; called by muse, mutect2, varscan2
- BLM | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs372013507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLVRA | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 243/1450 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs377670975; called by muse, mutect2, varscan2
- BMI1 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 67/391 reads (17%) | catalogued as COSV64959722; called by muse, mutect2, varscan2
- BMP1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 112/1238 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV60479018; called by muse, mutect2
- BMP1 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 31/523 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100109595, COSV100109629; called by muse, mutect2
- BMP2K | c.3225T>A p.H1075Q | Missense Mutation (SNP) | VAF 105/501 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV99784976; called by muse, mutect2, varscan2
- BMP3 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 148/943 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); catalogued as rs147415195; called by muse, varscan2
- BMP4 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 82/566 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs777345984, COSV99817008; called by muse, mutect2, varscan2
- BMP5 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 219/1248 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs879626914; called by muse, mutect2, varscan2
- BMP7 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); catalogued as rs766490422, COSV67780297; called by muse, mutect2, varscan2
- BMP8A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as rs1397794031; called by mutect2, varscan2
- BMP8B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 62/648 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs775172302; called by muse, mutect2
- BMPR2 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1319282096; called by muse, mutect2, varscan2
- BMS1 | c.2642G>A p.R881Q | Missense Mutation (SNP) | VAF 150/803 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747527498; called by muse, mutect2, varscan2
- BMX | c.1867C>A p.L623M | Missense Mutation (SNP) | VAF 162/784 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100564621; called by muse, mutect2, varscan2
- BOC | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56355207; called by muse, mutect2, varscan2
- BOC | c.1832G>T p.R611M | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99849687; called by muse, mutect2, varscan2
- BOD1L1 | c.6578C>T p.P2193L | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229984512; called by muse, varscan2
- BORCS7 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs1215818434, COSV54916822; called by muse, mutect2, varscan2
- BPGM | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs745809683; called by muse, mutect2, varscan2
- BPIFA1 | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.782); catalogued as COSV100845623; called by muse, mutect2, varscan2
- BPIFB6 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 129/770 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs550355845, COSV62754291, COSV62755074; called by muse, mutect2, varscan2
- BPNT1 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59038866; called by muse, mutect2, varscan2
- BPNT1 | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196486865; called by muse, mutect2, varscan2
- BPTF | c.8950C>T p.R2984* | Nonsense Mutation (SNP) | VAF 50/328 reads (15%) | catalogued as COSV58845424; called by muse, mutect2, varscan2
- BRCA1 | c.4769T>C p.V1590A | Missense Mutation (SNP) | VAF 129/786 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs773524529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4037C>A p.T1346N | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); catalogued as rs1555283519, CD993687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4925A>C p.N1642T | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs80358718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6235G>A p.V2079M | Missense Mutation (SNP) | VAF 61/432 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as CD129039; called by muse, mutect2, varscan2
- BRD1 | c.2461G>A p.A821T (on ENST00000216267 / NM_001349940.1; = p.A952T on NM_001304808.3) | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1453676903; called by muse, varscan2
- BRD1 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 74/440 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53457027; called by muse, mutect2, varscan2
- BRD3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs778306761; called by muse, varscan2
- BRD4 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs774596084, COSV54594527; called by muse, varscan2
- BRINP1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.151); catalogued as rs763882375, COSV56292953; called by mutect2, varscan2
- BRINP2 | c.1235+2T>C p.X412_splice | Splice Site (SNP) | VAF 20/370 reads (5%) | catalogued as COSV100838299; called by muse, mutect2
- BRINP3 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 229/879 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs1209013098, COSV66538570; called by muse, mutect2, varscan2
- BRMS1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV60820597; called by muse, mutect2
- BRPF3 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 113/725 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240061544; called by muse, mutect2, varscan2
- BRWD1 | c.6809G>A p.R2270Q | Missense Mutation (SNP) | VAF 64/350 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1387048628, COSV59000046; called by muse, mutect2, varscan2
- BSDC1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 54/600 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1347180522; called by muse, mutect2
- BSG | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as rs753877511, COSV100345132; called by muse, mutect2, varscan2
- BSN | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1336122554; called by muse, mutect2, varscan2
- BTAF1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200229615, COSV56436282; called by muse, varscan2
- BTBD10 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 139/744 reads (19%) | catalogued as rs1245744628, COSV53398654; called by muse, mutect2, varscan2
- BTBD16 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 94/597 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs202210822, COSV53260423; called by muse, mutect2, varscan2
- BTBD8 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866260203, COSV61547194; called by muse, mutect2, varscan2
- BTD | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 132/684 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57729200; called by muse, mutect2, varscan2
- BTD | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 111/549 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs149690919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 194/763 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58117689; called by muse, mutect2, varscan2
- BTN1A1 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 178/1039 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55067481; called by muse, mutect2, varscan2
- BTN3A1 | c.802T>C p.Y268H | Missense Mutation (SNP) | VAF 98/580 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as COSV99175627; called by muse, mutect2, varscan2
- BTN3A2 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356681175; called by mutect2, varscan2
- BTNL2 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs185078933; called by muse, mutect2, varscan2
- BTNL8 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs868531369; called by muse, mutect2, varscan2
- BTNL9 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1209207691; called by muse, mutect2, varscan2
- C11orf1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs139660891; called by muse, mutect2, varscan2
- C12orf4 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs559422887, COSV99712965; called by muse, mutect2, varscan2
- C15orf39 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 42/509 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs543541900; called by muse, mutect2
- C16orf70 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 294/1562 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs751390076, COSV99531126; called by muse, mutect2, varscan2
- C16orf78 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 87/600 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs144505396; called by muse, mutect2, varscan2
- C16orf86 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427204645; called by muse, mutect2, varscan2
- C19orf18 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as CM148469, COSV58704943; called by muse, mutect2, varscan2
- C19orf44 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs910699019; called by muse, mutect2
- C19orf44 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs999432590; called by muse, mutect2
- C19orf44 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs762513557, COSV52225970; called by muse, mutect2, varscan2
- C1QTNF1 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 127/714 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.111); catalogued as COSV59263078; called by muse, mutect2, varscan2
- C1QTNF1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769162624, COSV100189980; called by muse, mutect2, varscan2
- C1QTNF3 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 80/528 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1255813346, COSV51468465, COSV99180691; called by muse, varscan2
- C1orf116 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.693); catalogued as rs706846; called by muse, varscan2
- C1orf162 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59059784; called by muse, mutect2
- C1orf174 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.248); catalogued as COSV100851732; called by muse, mutect2
- C1orf210 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs945196801; called by muse, mutect2
- C1orf74 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 128/724 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs150951869; called by muse, varscan2
- C20orf194 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | catalogued as rs758002344; called by muse, mutect2, varscan2
- C20orf194 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV52703600; called by muse, mutect2, varscan2
- C2CD3 | c.4349C>A p.P1450H | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.928); catalogued as rs1055511737; called by muse, mutect2
- C2CD3 | c.3506A>G p.N1169S | Missense Mutation (SNP) | VAF 146/645 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs773972982; called by muse, mutect2, varscan2
- C2CD3 | c.2843G>A p.R948Q | Missense Mutation (SNP) | VAF 76/508 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768909968; called by muse, mutect2, varscan2
- C2orf16 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 197/687 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs768227348, COSV100820845; called by muse, mutect2, varscan2
- C2orf16 | c.4964G>A p.R1655H | Missense Mutation (SNP) | VAF 338/1463 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs766483410, COSV62675336; called by muse, mutect2, varscan2
- C3AR1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs768607158, COSV50818743, COSV99368193; called by muse, mutect2, varscan2
- C3orf38 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 130/670 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs373620957; called by muse, mutect2, varscan2
- C4orf33 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99828954; called by muse, mutect2, varscan2
- C5orf38 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.268); catalogued as rs1231627026; called by muse, mutect2, varscan2
- C5orf51 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 115/658 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370411797, COSV101069011; called by muse, varscan2
- C6 | c.2519G>A p.G840D | Missense Mutation (SNP) | VAF 152/935 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV54721246; called by muse, mutect2, varscan2
- C6 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54704439; called by muse, mutect2, varscan2
- C6orf118 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs781300980, COSV57813918; called by muse, mutect2, varscan2
- C6orf47 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 35/776 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs1307790164; called by muse, mutect2
- C7 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV100495196; called by muse, mutect2, varscan2
- C7orf25 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772960316, COSV100623625; called by muse, mutect2, varscan2
- C7orf25 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.134); catalogued as COSV63273331; called by muse, mutect2, varscan2
- C7orf25 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 157/783 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV63274326; called by muse, mutect2, varscan2
- C7orf31 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV52221099; called by muse, mutect2, varscan2
- C8A | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 153/710 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559111946, COSV63483217; called by muse, mutect2, varscan2
- C8orf34 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 108/628 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV61375499; called by muse, mutect2, varscan2
- C8orf58 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as rs771271445; called by muse, mutect2, varscan2
- C8orf76 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 87/483 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs138956285; called by muse, mutect2, varscan2
- C9orf43 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs145109883; called by muse, mutect2, varscan2
- CABIN1 | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 94/580 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs747404346; called by muse, mutect2, varscan2
- CACHD1 | c.2399C>A p.S800Y | Missense Mutation (SNP) | VAF 80/761 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99261575; called by muse, mutect2, varscan2
- CACNA1A | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377011125, COSV100801940; called by muse, varscan2
- CACNA1C | c.4609C>T p.R1537C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59704693; called by muse, mutect2
- CACNA1D | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 97/602 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55444116, COSV55467119; called by muse, mutect2, varscan2
- CACNA1E | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs375559507; called by muse, varscan2
- CACNA1E | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 98/661 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377338098; called by muse, varscan2
- CACNA1E | c.2933C>A p.A978D | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV62405524, COSV62408644; called by muse, mutect2, varscan2
- CACNA1G | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs766821069; called by muse, varscan2
- CACNA1H | c.4714C>T p.R1572W | Missense Mutation (SNP) | VAF 116/577 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs199693105; ClinVar: likely benign; called by muse, mutect2
- CACNA1I | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 97/674 reads (14%) | catalogued as rs1025122085; called by muse, mutect2, varscan2
- CACNA1S | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs140453525; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CACNA1S | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 95/684 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs370861322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.2018C>T p.S673L (on ENST00000356253 / NM_001366867.1; = p.S661L on NM_000722.4) | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs779137994, COSV62373938; called by muse, mutect2, varscan2
- CACNA2D3 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421806647, COSV55531132; called by muse, mutect2, varscan2
- CACNA2D4 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1358826279; called by muse, mutect2
- CACNB2 | c.1898G>A p.R633H (on ENST00000324631 / NM_201596.3; = p.R578H on NM_000724.4) | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.468); catalogued as rs780045364, COSV99994544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACTIN | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 89/412 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs538539255, COSV50276258; called by muse, mutect2, varscan2
- CAD | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs918097614, COSV53032195; called by muse, mutect2, varscan2
- CADM1 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 109/651 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs145171991; called by muse, mutect2, varscan2
- CADM2 | c.622G>A p.E208K (on ENST00000407528 / NM_001167674.2; = p.E210K on NM_153184.4) | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.793); catalogued as rs201652066, COSV67409614; called by muse, mutect2, varscan2
- CADPS2 | c.2198T>C p.I733T | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs1453353132; called by muse, mutect2, varscan2
- CALCR | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs1428691041; called by muse, mutect2, varscan2
- CALU | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369749257; called by muse, mutect2, varscan2
- CAMK2D | c.947-1G>T p.X316_splice | Splice Site (SNP) | VAF 24/260 reads (9%) | catalogued as COSV99595237; called by muse, mutect2
- CAMK4 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1393937416, COSV56682838; called by muse, mutect2, varscan2
- CAMP | c.328C>T p.R110W (on ENST00000296435; = p.R107W on NM_004345.5) | Missense Mutation (SNP) | VAF 75/534 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs779987355, COSV56481837; called by muse, varscan2
- CAMSAP1 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs1010350508; called by muse, mutect2, varscan2
- CAMSAP1 | c.1682G>T p.R561M | Missense Mutation (SNP) | VAF 168/1177 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV56726620; called by muse, mutect2, varscan2
- CAMSAP3 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV50355115; called by muse, mutect2, varscan2
- CAMTA1 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 41/525 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.519); catalogued as COSV57922403; called by muse, mutect2
- CAMTA1 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 75/978 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs1310943864, COSV57924430; called by muse, mutect2
- CAMTA2 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 93/581 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61834847; called by muse, mutect2, varscan2
- CAND1 | c.2284C>A p.L762M | Missense Mutation (SNP) | VAF 45/650 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101607311; called by muse, mutect2
- CAND2 | c.984G>T p.E328D (on ENST00000456430 / NM_001162499.2; = p.E235D on NM_012298.3) | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV55988796; called by muse, mutect2, varscan2
- CAP2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 75/434 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs780812899, COSV57738222; called by muse, mutect2, varscan2
- CAPN1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54196873; called by muse, mutect2, varscan2
- CAPN11 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 197/1109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746096764, COSV101291995; called by muse, mutect2, varscan2
- CAPN15 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs991904599; called by muse, mutect2
- CAPN15 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54834111; called by muse, mutect2, varscan2
- CAPN15 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs759603193, COSV99562474; called by muse, mutect2, varscan2
- CAPN5 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs781003018; called by muse, mutect2, varscan2
16,801 further variants in this file (12,125 protein-altering or splice-affecting, 4,289 silent, 387 other) are not listed here.
